Somatic mutation profile of tumor specimen MMRF_2733_1_BM_CD138pos (aliquot MMRF_2733_1_BM_CD138pos_T1_KHS5U_L14879) from MMRF case MMRF_2733, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 46.2 years (16,864 days).
Specimen MMRF_2733_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3702cb69-2816-48a5-9f21-65bafb6d66fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2733_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2733_1_PB_WBC_C3_KHS5U_L14880; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bc118c4-7b7e-46c4-ad3e-9345179a4223

The open-access MAF lists 59 somatic variants for this specimen: 17 protein-altering or splice-affecting, 9 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 11, 3'UTR 10, Silent 9, 5'UTR 5, 5'Flank 4, 3'Flank 2, Nonsense Mutation 2, In Frame Del 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 93/208 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs397507510, CD055729, CM021127, CM101143, COSV61004841, COSV61006072, COSV61006164; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASXL2 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 96/191 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55456278, COSV55462264; called by muse, mutect2, varscan2
- EDAR | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1482311193; called by muse, mutect2, varscan2
- F5 | c.6298C>T p.R2100C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs775843029; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OTOG | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs542646349; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTGES2 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as rs776251294, COSV52969443, COSV52969452; called by muse, mutect2
- ABCC11 | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 55/121 reads (45%) | called by muse, mutect2, varscan2
- ALG2 | c.692_694del p.I231del | In Frame Del (DEL) | VAF 41/185 reads (22%) | called by mutect2, pindel, varscan2
- ATP13A3 | c.1920_1930del p.V641* | Frame Shift Del (DEL) | VAF 155/288 reads (54%) | called by mutect2, varscan2
- FIGNL2 | c.1004_1009del p.S335_V337delinsF | In Frame Del (DEL) | VAF 22/51 reads (43%) | called by mutect2, pindel, varscan2
- IGHV1-69D | c.27T>A p.F9L | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.026); called by muse, varscan2
- IGKV2-30 | c.306G>T p.R102S | Missense Mutation (SNP) | VAF 74/136 reads (54%) | SIFT tolerated (0.43); PolyPhen benign (0.02); called by mutect2, varscan2
- IGKV2-30 | c.64G>C p.V22L | Missense Mutation (SNP) | VAF 92/157 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, varscan2
- LHFPL4 | c.83T>A p.I28N | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, varscan2
- SLC28A3 | c.42C>A p.Y14* | Nonsense Mutation (SNP) | VAF 86/332 reads (26%) | called by muse, mutect2, varscan2
- SMARCAD1 | c.2604G>C p.Q868H | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ZNF568 | c.1045C>G p.L349V | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH5 | c.11889G>A p.S3963= | Silent (SNP) | VAF 64/134 reads (48%) | catalogued as rs781513459; called by muse, mutect2, varscan2
- FBXL16 | c.816G>A p.E272= | Silent (SNP) | VAF 57/106 reads (54%) | catalogued as rs1298214607; called by muse, mutect2, varscan2
- IGHV2-70 | c.135G>T p.G45= | Silent (SNP) | VAF 46/86 reads (53%) | catalogued as rs8010256; called by muse, varscan2
- IGHV2-70 | c.102A>G p.T34= | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as rs559222113; called by muse, varscan2
- KIF26B | c.5940G>A p.P1980= | Silent (SNP) | VAF 55/123 reads (45%) | catalogued as rs375988013; called by muse, mutect2, varscan2
- MYH11 | c.690C>T p.N230= | Silent (SNP) | VAF 40/76 reads (53%) | catalogued as rs561105158; ClinVar: likely benign; called by muse, varscan2
- TRIM67 | c.159G>A p.R53= | Silent (SNP) | VAF 40/83 reads (48%) | called by mutect2, varscan2
- TTYH2 | c.288C>T p.A96= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as rs201207644, COSV53909547, COSV99482930; called by muse, mutect2, varscan2
- ZNF717 | c.1854C>A p.P618= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV68858919; called by muse, mutect2
- AC020910.3 | n.381G>C | RNA (SNP) | VAF 55/89 reads (62%) | called by muse, mutect2, varscan2
- AC092368.2 | chr16:46568801 C>T | 5'Flank (SNP) | VAF 71/156 reads (46%) | called by muse, mutect2, varscan2
- ADRB1 | c.-196G>A | 5'UTR (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- ARHGEF11 | chr1:157045248 C>T | 5'Flank (SNP) | VAF 31/72 reads (43%) | catalogued as rs946315743; called by muse, mutect2, varscan2
- ARID1A | c.-322C>T | 5'UTR (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- ATP5F1A | c.-48-67T>A | Intron (SNP) | VAF 29/67 reads (43%) | called by muse, mutect2, varscan2
- BMP6 | c.*1088_*1120del | 3'UTR (DEL) | VAF 18/47 reads (38%) | called by mutect2, pindel
- BRD9 | c.-4C>T | 5'UTR (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- CFAP298 | c.666+76C>T | Intron (SNP) | VAF 59/139 reads (42%) | catalogued as rs760201589, COSV99267462; called by muse, mutect2, varscan2
- CHST2 | c.*295T>A | 3'UTR (SNP) | VAF 39/114 reads (34%) | called by muse, mutect2, varscan2
- CSMD3 | c.7885+136A>T | Intron (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- DAAM2 | c.1954-33A>G | Intron (SNP) | VAF 30/66 reads (45%) | catalogued as rs1245927638; called by mutect2, varscan2
- DENND3 | c.383+859T>C | Intron (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- DOCK8 | chr9:213376 G>A | 5'Flank (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- DST | c.21591+99_21591+103del | Intron (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- FAM3B | c.20-91G>A | Intron (SNP) | VAF 67/195 reads (34%) | catalogued as rs777179637; called by muse, mutect2, varscan2
- FAT3 | c.*899A>G | 3'UTR (SNP) | VAF 56/198 reads (28%) | catalogued as rs552995066; called by muse, mutect2, varscan2
- IRAK3 | c.*2926A>G | 3'UTR (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- ITPK1 | c.*805T>C | 3'UTR (SNP) | VAF 85/195 reads (44%) | called by muse, mutect2, varscan2
- KTN1 | c.3091-767G>A | Intron (SNP) | VAF 68/140 reads (49%) | called by muse, mutect2, varscan2
- LATS2 | c.*794G>T | 3'UTR (SNP) | VAF 24/76 reads (32%) | called by muse, mutect2, varscan2
- METTL7A | c.*1656T>C | 3'UTR (SNP) | VAF 3/9 reads (33%) | catalogued as rs3209374; called by muse, mutect2, varscan2
- MUS81 | c.*363T>C | 3'UTR (SNP) | VAF 60/137 reads (44%) | catalogued as rs1401787938; called by muse, mutect2, varscan2
- NAV2 | c.2977-33G>C | Intron (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- NPC2 | chr14:74479376 C>A | 3'Flank (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- PAX1 | c.*119T>C | 3'UTR (SNP) | VAF 62/137 reads (45%) | called by muse, varscan2
- QARS1 | c.517-144G>A | Intron (SNP) | VAF 41/150 reads (27%) | called by muse, varscan2
- SIPA1L2 | c.-1C>T | 5'UTR (SNP) | VAF 55/105 reads (52%) | called by muse, mutect2, varscan2
- SORBS2 | c.-177G>A | 5'UTR (SNP) | VAF 23/44 reads (52%) | called by muse, mutect2, varscan2
- SPG7 | chr16:89507685 C>G | 5'Flank (SNP) | VAF 71/191 reads (37%) | called by muse, mutect2, varscan2
- TIFAB | c.*4837T>C | 3'UTR (SNP) | VAF 52/108 reads (48%) | called by muse, mutect2, varscan2
- TMEFF2 | c.439+1359del | Intron (DEL) | VAF 22/38 reads (58%) | catalogued as rs60511155; called by mutect2, varscan2
- TRIM67 | chr1:231220324 G>C | 3'Flank (SNP) | VAF 49/124 reads (40%) | called by muse, mutect2, varscan2
